Gene-level copy-number profile of tumor specimen TCGA-A7-A0DC-01A from TCGA case TCGA-A7-A0DC, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 63.8 years (23,294 days).
Specimen TCGA-A7-A0DC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.5bfd4ac0-78fb-4ee5-ac75-7e20a268685c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A0DC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/0d382b4e-45fb-446a-a593-4a0553eb54aa

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 5,238; copy number 3: 17,294; copy number 4: 30,913; copy number 5: 1,333; copy number 6: 574; copy number 7: 1,574; copy number 8: 552; copy number 9: 1,065; copy number 10: 1,175; copy number 11: 44; copy number 12: 42; copy number 13: 13.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,339 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:35,235,475–38,176,730, 58 genes, copy number 9–12: UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P.
- chr8:77,399,072–145,066,685, 1,063 genes, copy number 10 (broad region; genes not listed).
- chr11:66,744,451–66,843,516, 1 gene, copy number 10 (within-gene range 7–10): C11orf80.
- chr11:66,771,246–73,876,901, 262 genes, copy number 9–13 (broad region; genes not listed).
- chr16:46,469,341–48,498,601, 55 genes, copy number 9: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2, NETO2, ITFG1-AS1, RPL23AP72, ITFG1, AC007494.2, AC007494.3, AC007494.1, AC007533.1, Y_RNA, 5S_rRNA, PHKB, RNA5SP425, AC007599.2, AC007599.1, EIF4BP5, NDUFA5P11, LINC02133, AC141846.1, LINC02192, LINC02134, AC096996.3, AC096996.1, ABCC12, AC096996.2, ABCC11, LONP2, UBA52P8, AC023818.1, SIAH1, Metazoa_SRP, AC026470.3, AC026470.1, MOCS1P1.
- chr16:49,066,567–49,275,579, 4 genes, copy number 10 (within-gene range 7–10): MTND4LP25, AC044798.3, AC044798.1, AC044798.2.
- chr20:30,294,550–64,313,132, 896 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
